MMRF case MMRF_2035 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0e6384ff-f974-4748-8248-87b3763268d2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.8 years (26,948 days); ISS stage: III; Days to last known disease status: 86 days; Days to last follow up: 86 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 2): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1600 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 6.39 g/L; Immunoglobulin A 21 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 29.8 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 423 µmol/L; Blood Urea Nitrogen 29.6 mmol/L; Calcium 3.15 mmol/L; Albumin 33 g/L; Total Protein 8.8 g/dL; Glucose 4.24 mmol/L.
- Day 86 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 6.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.27 mg/dL; Immunoglobulin G 13.9 g/L; Immunoglobulin A 2.66 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 7.09 µg/mL; Hemoglobin 8.62 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 7.1 g/dL; Glucose 7.04 mmol/L.

Other clinical attributes
- Day 1: Weight: 81 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2035_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2035_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
